Somatic mutation profile of tumor specimen TCGA-74-6581-01A (aliquot TCGA-74-6581-01A-11D-1845-08) from TCGA case TCGA-74-6581, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.4 years (28,263 days).
Specimen TCGA-74-6581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8e06d91-627c-4d04-8c03-e34ab5fde518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6581-10A (Blood Derived Normal), aliquot TCGA-74-6581-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb746c48-50c7-47cf-a977-fb09ecb95dd1

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 4, Splice Region 2, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV99917164; called by muse, mutect2, varscan2
- ACOX2 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1317973851, COSV57147955; called by muse, mutect2, varscan2
- BTBD7 | c.1528A>T p.R510* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as COSV100597622; called by muse, mutect2, varscan2
- CACNA1G | c.5437C>T p.R1813W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661380; called by muse, mutect2, varscan2
- CDC40 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100309189; called by muse, mutect2, varscan2
- COL12A1 | c.8915G>C p.G2972A | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485581; called by muse, mutect2, varscan2
- CUX1 | c.2930G>A p.S977N | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99470845; called by muse, mutect2, varscan2
- DCTN1 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs967117932, COSV62620221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECEL1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs1484934426, COSV100458541; called by muse, mutect2, varscan2
- FGF5 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs745662451, COSV56892905; called by muse, mutect2, varscan2
- FNIP2 | c.234G>A p.Q78= | Splice Region (SNP) | VAF 76/182 reads (42%) | catalogued as COSV100032315; called by muse, mutect2, varscan2
- GALNT9 | c.1666A>C p.S556R (on ENST00000328957 / NM_001122636.2; = p.S190R on NM_021808.3) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1274452743, COSV100201177; called by muse, mutect2, varscan2
- HOXA6 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99762164; called by muse, mutect2, varscan2
- IGSF9 | c.1420C>T p.R474* (on ENST00000368094 / NM_001135050.2; = p.R458* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as rs569197292, COSV63639710; called by muse, mutect2
- IL1RL2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs868856349, COSV51817819; called by muse, mutect2, varscan2
- INPP4B | c.1025T>G p.I342R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99523461; called by muse, mutect2, varscan2
- KCNB2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764013780, COSV73049004; called by muse, mutect2, varscan2
- KDM5C | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1428740468, COSV64767426, COSV64767953; called by muse, mutect2, varscan2
- KDR | c.69T>G p.G23= | Splice Region (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99816999; called by muse, mutect2, varscan2
- MAMDC2 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101013979; called by muse, mutect2, varscan2
- OR11H12 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as rs774926646, COSV101612468; called by muse, mutect2, varscan2
- PEAK1 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373048442; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs372735637; called by muse, mutect2, varscan2
- SLC10A1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs200052753, COSV99384241; called by muse, mutect2, varscan2
- SMPD4 | c.2002A>G p.I668V (on ENST00000409031 / NM_017951.4; = p.I639V on NM_017751.4) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100302265; called by muse, varscan2
- SNPH | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771345502, COSV67871539; called by muse, mutect2, varscan2
- TOP2B | c.3140G>A p.R1047Q (on ENST00000264331 / NM_001330700.2; = p.R1042Q on NM_001068.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553640695, COSV99979408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM3 | c.582del p.F195Lfs*20 (on ENST00000357533 / NM_001366142.2; = p.F40Lfs*20 on NM_020952.6) | Frame Shift Del (DEL) | VAF 82/228 reads (36%) | catalogued as COSV62475328; called by mutect2, pindel, varscan2
- ZDBF2 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as rs747914912, COSV65622744; called by muse, mutect2, varscan2
- ZNF800 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs757618541, COSV99757771; called by muse, mutect2, varscan2
- ZNF99 | c.958A>T p.K320* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV101233753; called by muse, mutect2, varscan2
- ARMH3 | c.871_872del p.V292Tfs*4 | Frame Shift Del (DEL) | VAF 38/68 reads (56%) | called by pindel, varscan2
- FCGBP | c.3014A>G p.N1005S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1A3 | c.834G>A p.T278= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs751008211, COSV100320279; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYTN | c.282G>A p.T94= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1173370474; called by muse, mutect2, varscan2
- ENTPD5 | c.456C>T p.F152= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV100592167; called by muse, mutect2, varscan2
- FLI1 | c.624C>T p.T208= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as rs770937644, COSV99857514; called by muse, mutect2, varscan2
- LILRB1 | c.2085C>T p.Y695= (on ENST00000427581; = p.Y644= on NM_006669.6) | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as rs1395375851, COSV100207047; called by muse, mutect2, varscan2
- MEPCE | c.1392G>A p.K464= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV52769950; called by muse, mutect2, varscan2
- NLRP7 | c.2271A>G p.R757= (on ENST00000340844 / NM_206828.3; = p.R729= on NM_139176.3) | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV100051911; called by muse, mutect2, varscan2
- PCDHGB5 | c.1953C>T p.S651= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs375308173; called by muse, mutect2, varscan2
- PPP1R15A | c.1635G>A p.P545= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs376245715; called by muse, mutect2, varscan2
- PTPN1 | c.505C>A p.R169= | Silent (SNP) | VAF 61/309 reads (20%) | catalogued as COSV100860573; called by muse, mutect2, varscan2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 87/199 reads (44%) | catalogued as rs142804903; called by muse, mutect2, varscan2
- MLLT6 | c.819+201T>C | Intron (SNP) | VAF 33/83 reads (40%) | catalogued as rs770697245; called by muse, mutect2, varscan2
- PRRC2B | c.6226-927A>T | Intron (SNP) | VAF 113/281 reads (40%) | catalogued as COSV100260909; called by muse, mutect2, varscan2
